Gene-level copy-number profile of tumor specimen TCGA-VQ-A8PY-01A from TCGA case TCGA-VQ-A8PY, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 47.2 years (17,230 days).
Specimen TCGA-VQ-A8PY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.1708a9e4-0b6f-4402-a665-9958c0d7a5a8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A8PY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6db0d684-33bd-4848-843d-966dd396b7bd

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 49; copy number 1: 359; copy number 2: 13,849; copy number 3: 26,100; copy number 4: 9,712; copy number 5: 3,734; copy number 6: 4,567; copy number 7: 588; copy number 8: 141; copy number 9: 40; copy number 10: 194; copy number 11: 43; copy number 12: 57; copy number 13: 11; copy number 14: 8; copy number 16: 9; copy number 18: 124; copy number 22: 139; copy number 23: 20; copy number 28: 5; copy number 31: 19; copy number 33: 4; copy number 36: 45.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A8PY-01A-11D-A40Z-01): tumor purity 0.32, ploidy 3.34, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 47 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:21,566,763–24,321,377, 33 genes: AP001117.1, AF241725.1, LINC00317, LINC01425, AP000472.1, LINC01687, LINC00308, AP000705.2, AP000705.1, RNU4-45P, AP000561.1, MAPK6P2, AP000959.1, AP000949.1, AP001116.1, MIR6130, ZNF299P, MSANTD2P1, AP001255.1, RNU2-55P, D21S2088E, EEF1A1P1, TUBAP1, Y_RNA, AP000459.1, AP000961.1, AP000474.2, AP000474.1, AP000477.2, AP000477.3, AP000477.1, AP000470.1, LINC01689.
- chr21:27,358,885–28,137,611, 10 genes (within-gene range 0–2): AP001605.1, AP001604.1, EIF4A1P1, RPL10P1, NCSTNP1, LINC01673, LINC00113, AJ006995.1, LINC00314, LINC01697.
- chr21:30,089,717–30,216,097, 4 genes: AF096876.1, CLDN17, LINC00307, CLDN8.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,447 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:489,803–1,801,711, 18 genes, copy number 8–13 (within-gene range 3–13): TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1.
- chr8:1,801,125–1,801,192, 1 gene, copy number 8: MIR3674.
- chr8:5,506,068–8,782,479, 140 genes, copy number 14–22 (broad region; genes not listed).
- chr8:10,050,485–20,226,819, 221 genes, copy number 11–36 (within-gene range 2–36) (broad region; genes not listed).
- chr8:36,764,445–38,409,527, 53 genes, copy number 10–33: RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4, AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2.
- chr8:38,408,048–38,426,096, 2 genes, copy number 10: AC087623.3, AC087623.1.
- chr12:25,195,216–29,784,759, 93 genes, copy number 10–36 (broad region; genes not listed).
- chr14:30,893,799–35,029,686, 68 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr14:36,298,564–40,390,547, 61 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr14:92,253,493–94,130,253, 40 genes, copy number 9: AL133240.1, RNU6-366P, AL133240.2, SLC24A4, RIN3, LGMN, GOLGA5, LINC02833, LINC02287, CHGA, ITPK1, ITPK1-AS1, CYB5AP3, MOAP1, TMEM251, AL110118.1, GON7, UBR7, AL132838.1, BTBD7, AL132838.2, UNC79, AL122023.1, COX8C, Y_RNA, RNU6-1258P, AL157858.2, PRIMA1, AL132642.2, FAM181A-AS1, FAM181A, ASB2, AL132642.1, MIR4506, CCDC197, OTUB2, DDX24, IFI27L1, IFI27, IFI27L2.
- chr14:105,536,861–106,875,071, 199 genes, copy number 7 (broad region; genes not listed).
- chr18:45,212,995–51,283,896, 135 genes, copy number 8–22 (within-gene range 3–22) (broad region; genes not listed).
- chr18:53,480,825–54,959,461, 22 genes, copy number 10: LINC01917, LINC01919, RPL29P32, AC090666.1, MBD2, SNORA37, AC093462.1, POLI, STARD6, C18orf54, SNRPGP2, CUPIN1P, AC090897.1, AC091135.1, AC091135.2, DYNAP, RAB27B, RPSAP57, AC007673.1, AC098848.1, CCDC68, MAP1LC3P.
- chr18:65,750,252–69,055,189, 36 genes, copy number 7–10 (within-gene range 5–10): CDH7, AC023394.2, AC023394.1, PRPF19P1, CDH19, RNU6-1037P, MIR5011, RPL31P9, AC091042.1, AC110597.1, DSEL, AC110597.3, AC114689.3, AC022662.1, AC022655.1, FAM32DP, AC114689.1, LINC01903, AC114689.2, AC100844.1, AC068112.1, AC005909.2, LINC01912, AC022968.1, AC005909.1, AKR1B10P2, MTL3P, TMX3, CCDC102B, AC040896.1, AC022035.1, RNU6-39P, SDHCP1, AC096708.2, AC096708.3, AC096708.1.
- chr20:4,590,993–4,823,608, 8 genes, copy number 10: AL121916.1, RPS4XP2, PRNP, PRND, PRNT, IDI1P3, AL133396.1, RASSF2.
- chr20:4,868,984–4,869,118, 1 gene, copy number 10: AL389886.1.
- chr20:15,280,764–15,985,876, 4 genes, copy number 7: RNA5SP475, AL121584.1, ENSAP1, AL079338.1.
- chr20:19,000,709–19,722,926, 6 genes, copy number 12 (within-gene range 12–24): AL135936.1, AL136090.2, SLC24A3, AL136090.1, SLC24A3-AS1, AL121830.1.
- chr20:28,563,850–38,772,520, 305 genes, copy number 7–10 (broad region; genes not listed).
- chr20:41,382,383–43,189,970, 13 genes, copy number 7 (within-gene range 5–7): AL031667.1, CHD6, AL031667.2, AL031667.3, RPL12P11, RNU6-1018P, AL133229.1, AL049812.2, AL049812.1, AL049812.3, PTPRT, AL035666.1, AL031656.1.
- chr20:50,930,984–52,670,578, 20 genes, copy number 12–16 (within-gene range 5–16): ADNP-AS1, DPM1, MOCS3, AL050404.1, KCNG1, AL121785.1, RPSAP1, NFATC2, MIR3194, ATP9A, AL138807.1, SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1, LINC01524, AL109610.1.
- chr20:58,228,940–58,309,451, 1 gene, copy number 13 (within-gene range 4–13): PPP4R1L.

Autosomal genes at a single copy (total copy number 1): 357. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
